CPTAC case C3L-00144 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7cb81ac8-33c5-4a38-bddf-68699f40b022

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1957; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 58.8 years (21,487 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 578 days (1.6 years); Days to last follow up: 578 days (1.6 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2 cm (a second GDC size field records 3.1 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 26; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 366 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 578 days (1.6 years); Disease response: Tumor Free.
- Days to follow up: 578 days (1.6 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 71 kg; Height: 165 cm; BMI: 26.08; DLCO (% of predicted): 41; FEV1/FVC after bronchodilator (%): 43; FEV1/FVC before bronchodilator (%): 41; FEV1 after bronchodilator (% of reference): 41; FEV1 before bronchodilator (% of reference): 41.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 42; Cigarettes per day: 20; Tobacco smoking onset year: 1973; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 49.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00144-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 233 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00144-21: Section location: Left Lower Lobe; Percent tumor nuclei: 70; Percent necrosis: 0.
- Sample C3L-00144-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 220 mg; Time between excision and freezing: 25 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00144-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
